Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A234, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A234-01A (Primary Tumor).

[page 1 of 4]
I.P.A.A. Discrepancy		☒

Print this Page

Specimen Description

Surgical Pathology Report

Patient Name: [REDACTED]

Accession #: [REDACTED]

Med. Rec #: [REDACTED]

Submitting Physician: [REDACTED]

100-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, nos c73.9 lw 4/8/11

*****Clinical History*****

Preop diagnosis and patient history: Papillary thyroid cancer.

*****Final Pathologic Diagnosis*****

- A. Prethyroid Lymph Node, biopsy:
- Papillary Thyroid Carcinoma Metastatic to Two of Two Lymph Nodes (2/2).
- B. ? Thyroid Gland, biopsy:
- Benign Thyroid Tissue.
- C. Right Thyroid Lobe, biopsy:
- Benign Thyroid Tissue.
- D. Thyroid Gland, total thyroidectomy:
- Papillary Thyroid Carcinoma of Right Lobe of Thyroid see synoptic report.
- Left Thyroid and Isthmus, Negative for Carcinoma.

Electronically Signed By
[REDACTED]
[REDACTED]

*****Addendum Report*****

Addendum

Status: Signed Out

In the synoptic report the number of positive lymph nodes is 2, not zero as originally stated, and the pTNM should read T2 N1 Mx instead of T2 N0 Mx. The correct number of positive nodes was accurately stated in the specimen A diagnosis line.

[page 2 of 4]
Sex: F

Specimen Description

Surgical Pathology Report

*****Clinical History*****

Preop diagnosis and patient history: Papillary thyroid cancer.

*****Final Pathologic Diagnosis*****

- A. Prethyroid Lymph Node, biopsy:
- Papillary Thyroid Carcinoma Metastatic to Two of Two Lymph Nodes (2/2).
- B. ? Thyroid Gland, biopsy:
- Benign Thyroid Tissue.
- C. Right Thyroid Lobe, biopsy:
- Benign Thyroid Tissue.
- D. Thyroid Gland, total thyroidectomy:
- Papillary Thyroid Carcinoma of Right Lobe of Thyroid see synoptic report.
- Left Thyroid and Isthmus, Negative for Carcinoma.

*****Addendum Report*****

Addendum

Status: Signed Out

In the synoptic report the number of positive lymph nodes is 2, not zero as originally stated, and the pTNM should read T2 N1 Mx instead of T2 N0 Mx. The correct number of positive nodes was accurately stated in the specimen A diagnosis line.

[page 3 of 4]
*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: total thyroidectomy

Tumor location: right lobe

Tumor size: 3.3 x 3.0 x 2.5 cm.

Histologic type: Papillary Thyroid Carcinoma, No Special Type.

Lymphatic/vascular invasion: absent

Thyroid Capsular invasion: absent

Tumor extent:

Confined to within the thyroid: yes

Multifocal: no

Lymph nodes:

Total number examined: 2

Number positive: none

pTNM: T2 N0 Mx.

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

AF1. Prethyroid node, cancer?: (FROZEN SECTION PERFORMED)

- Lymph node with metastatic thyroid carcinoma.

BF1. Thyroid gland vs. muscle?: (FROZEN SECTION PERFORMED)

- Benign thyroid.

Examining pathologist: [REDACTED]

*****SPECIMEN(S) RECEIVED:*****

A: Lymph node, ENT, REG

B: Thyroid, REG

C: Thyroid, REG

D: Thyroid, REG

*****GROSS DESCRIPTION:*****

The specimens are received in four properly labeled containers, two of which are frozen sections, with the patient's name and accession number.

A. The specimen is designated "prethyroid node cancer?" and consists of a 1.1 x 0.8 x 0.5 cm aggregate of tan-red soft tissue fragments. The specimen is entirely submitted for frozen section and resubmitted as received in cassette AF1. TE 1

[page 4 of 4]
B. The specimen is designated "thyroid gland vs. muscle?" and consists of a 2.0 x 1.0 x 0.5 cm portion of red-brown soft tissue. The specimen is entirely submitted for frozen section and resubmitted as received in cassette BF1. TE 1

C. The specimen is designated "right thyroid lobe" and consists of a 2.2 x 1.5 x 0.6 cm aggregate of multiple portions of shaggy tan-red soft tissue. TE 1

D. The specimen is designated "thyroid gland, one stitch=right superior pole, two stitches=right inferior pole, three stitches=left superior pole" and consists of a 21.2 gram thyroid gland that is 6.5 x 4.5 x 2.3 cm. The right lobe is markedly larger than the left. The capsular surface is tan-red and intact with no adherent possible lymph nodes or parathyroid glands identified. The left lobe displays a focal area of disruption. The thyroid gland is inked as follows: right lobe=blue, left lobe=black, isthmus=green. The specimen is serially sectioned revealing a 3.3 x 3.0 x 2.5 cm well circumscribed tan-red coarsely granular mass with focal areas of yellow flecks replacing the entire right lobe of the thyroid, and diffusely abuts the blue inked capsular surface. The isthmus and left lobes are grossly uninvolved by the mass. The uninvolved thyroid parenchyma is dark red to brown and glistening. ()

Summary of Cassettes: D1-5, representative sections of mass involving right thyroid lobe; D6, representative section of isthmus; D7-8, representative sections of left thyroid lobe with focal area of disruption in cassette D8

Lab Use Only: [REDACTED]

Gross description by: [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file c77aa555-8511-43f0-8993-4cb8b9ffe745 (TCGA-FE-A234.9161208D-62BA-4043-B3E6-25C0640B98E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).